Somatic mutation profile of tumor specimen 0DUUQ9 from CCDI case PBCLNW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DUUQ9: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb4a2f29-5719-4075-bcc4-ae3b1e80a90a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUUPT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9fb5a4f-5069-42af-a78e-87fae27c2bc5

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, 3'UTR 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSG1 | c.3133G>A p.V1045M | Missense Mutation (SNP) | VAF 87/260 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs140838956; called by muse, varscan2
- FAT2 | c.10049G>T p.G3350V | Missense Mutation (SNP) | VAF 150/393 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018478012, COSV55814083, COSV55825934; called by muse, varscan2
- HDC | c.1885G>T p.A629S | Missense Mutation (SNP) | VAF 112/273 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); called by muse, varscan2
- LRRK2 | c.4034G>T p.S1345I | Missense Mutation (SNP) | VAF 176/372 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- MRC1 | c.3125G>T p.R1042I | Missense Mutation (SNP) | VAF 112/269 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.117); called by muse, varscan2
- MYO9B | c.1893C>A p.F631L | Missense Mutation (SNP) | VAF 174/424 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, varscan2
- NF1 | c.3979G>T p.E1327* | Nonsense Mutation (SNP) | VAF 92/248 reads (37%) | called by muse, varscan2
- PEAR1 | c.2911C>A p.Q971K | Missense Mutation (SNP) | VAF 118/303 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, varscan2
- PPP3CB | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.035); called by muse, varscan2
- PTPRCAP | c.161G>T p.W54L | Missense Mutation (SNP) | VAF 72/331 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, varscan2
- TMEM102 | c.1516G>T p.G506W | Missense Mutation (SNP) | VAF 101/232 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, varscan2
- MUC12 | c.4389C>A p.G1463= (on ENST00000379442; = p.G1320= on NM_001164462.1) | Silent (SNP) | VAF 59/197 reads (30%) | catalogued as rs1480546520; called by muse, varscan2
- OS9 | c.1569C>A p.P523= | Silent (SNP) | VAF 128/323 reads (40%) | called by muse, varscan2
- UNC45A | c.2499G>T p.L833= | Silent (SNP) | VAF 30/247 reads (12%) | catalogued as COSV67793632; called by muse, varscan2
- SLC19A3 | c.*82G>T | 3'UTR (SNP) | VAF 14/78 reads (18%) | called by muse, varscan2
- TMEM183B | n.93C>T | RNA (SNP) | VAF 288/606 reads (48%) | catalogued as rs373272847; called by muse, varscan2
